Somatic mutation profile of tumor specimen TCGA-BP-5187-01A (aliquot TCGA-BP-5187-01A-01D-1429-08) from TCGA case TCGA-BP-5187, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.8 years (19,999 days).
Specimen TCGA-BP-5187-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f49e3881-8373-457d-9193-4c7108923f5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5187-11A (Solid Tissue Normal), aliquot TCGA-BP-5187-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ad65e8b-260e-47dd-833f-a48b91404b17

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 58/213 reads (27%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- VHL | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs869025631, CD141834, CM951280, HM971583, COSV56542714, COSV56543921; ClinVar: pathogenic; called by muse, varscan2
- ALPL | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV66376588; called by muse, mutect2, varscan2
- ARHGAP11A | c.410T>G p.L137W | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853122; called by muse, mutect2, varscan2
- ATG7 | c.240C>A p.C80* | Nonsense Mutation (SNP) | VAF 67/233 reads (29%) | catalogued as COSV61615343; called by muse, mutect2, varscan2
- BSND | c.775T>A p.W259R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64871331; called by muse, mutect2, varscan2
- CCKAR | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779987287, COSV55163646; called by muse, mutect2, varscan2
- CDH4 | c.1727C>G p.T576S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs1357387538, COSV64672141; called by muse, mutect2, varscan2
- CLCC1 | c.1615G>A p.G539R (on ENST00000356970 / NM_001377464.1; = p.G489R on NM_015127.5) | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV51444284; called by muse, mutect2, varscan2
- COX11 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54803768; called by muse, mutect2, varscan2
- CTNNA3 | c.1639G>C p.V547L | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65615269; called by muse, mutect2, varscan2
- DSE | c.855T>A p.F285L | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.763); catalogued as COSV59067033; called by muse, mutect2, varscan2
- FAM222B | c.719dup p.N241Efs*27 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs764940150; called by mutect2, varscan2
- FBLN2 | c.1817A>T p.D606V | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55490228; called by muse, mutect2, varscan2
- FMO2 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV52950102; called by muse, mutect2, varscan2
- GAA | c.2286A>T p.E762D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV56411705; called by muse, mutect2
- GPR158 | c.3089C>G p.S1030C | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as rs200285541, COSV66280836; called by muse, mutect2, varscan2
- GPR89B | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100032303; called by muse, mutect2, varscan2
- HDAC6 | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV61930437; called by muse, mutect2, varscan2
- HLA-E | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV64927906; called by muse, mutect2, varscan2
- IQGAP3 | c.4549G>A p.D1517N | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV63254063; called by muse, mutect2, varscan2
- KLK14 | c.464T>A p.I155N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV50070775; called by muse, mutect2
- MARK4 | c.1633T>C p.S545P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV53468279; called by muse, mutect2
- MCM7 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV57998417, COSV57998649; called by muse, mutect2, varscan2
- N4BP2L2 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57230154; called by muse, mutect2, varscan2
- POR | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV58695099; called by muse, mutect2, varscan2
- PPIC | c.593A>T p.K198M | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV60575189; called by muse, mutect2, varscan2
- PPL | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62050455; called by muse, mutect2, varscan2
- RENBP | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV60076961; called by muse, mutect2, varscan2
- S1PR3 | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV63981295; called by muse, mutect2, varscan2
- SAG | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV68592237; called by muse, mutect2, varscan2
- SIL1 | c.354-2A>T p.X118_splice | Splice Site (SNP) | VAF 75/286 reads (26%) | catalogued as COSV54536747; called by muse, mutect2, varscan2
- SLITRK2 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.415); catalogued as COSV59428220; called by muse, mutect2, varscan2
- SLU7 | c.772A>G p.R258G | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV51789898; called by muse, mutect2
- SPAG9 | c.3366T>G p.H1122Q (on ENST00000262013 / NM_001130528.3; = p.H1108Q on NM_003971.6) | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56242744; called by muse, mutect2, varscan2
- SSTR3 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60730259; called by muse, mutect2, varscan2
- TGM6 | c.981C>G p.D327E | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373537808, COSV52483748; called by muse, mutect2, varscan2
- THBS1 | c.2878T>C p.F960L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV52955383; called by muse, mutect2, varscan2
- TRAPPC11 | c.3353T>C p.V1118A | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV58218789; called by muse, mutect2
- UNC5A | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56171957; called by muse, mutect2, varscan2
- WASHC4 | c.1993A>G p.M665V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.079); catalogued as COSV59891948; called by muse, mutect2, varscan2
- ZNF257 | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV71311299; called by muse, mutect2, varscan2
- GNAS | c.624dup p.E209* | Frame Shift Ins (INS) | VAF 29/135 reads (21%) | called by mutect2, pindel, varscan2
- SMS | c.995del p.L332Rfs*39 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- ACO1 | c.2067C>T p.N689= | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as COSV59384468; called by muse, mutect2
- ADAMTS20 | c.1182A>C p.G394= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV67138105; called by muse, mutect2, varscan2
- BBS10 | c.294T>C p.H98= | Silent (SNP) | VAF 42/216 reads (19%) | catalogued as rs768441850, COSV53888525; called by muse, mutect2, varscan2
- CEP76 | c.114A>G p.E38= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as COSV50869713; called by muse, mutect2, varscan2
- DENND4B | c.309T>A p.V103= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV57845406; called by muse, mutect2, varscan2
- MPP5 | c.1086T>C p.P362= | Silent (SNP) | VAF 31/159 reads (19%) | catalogued as COSV55532226; called by muse, mutect2, varscan2
- SAMD14 | c.906T>C p.S302= (on ENST00000330175 / NM_001257359.2; = p.S330= on NM_174920.4) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV50304738; called by muse, mutect2, varscan2
- SGSM1 | c.789T>A p.V263= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV68513042; called by muse, mutect2, varscan2
- SLC4A10 | c.2814A>G p.L938= (on ENST00000446997 / NM_001354461.2; = p.L908= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV55797168; called by muse, mutect2, varscan2
- SPIN2A | c.714G>A p.V238= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs922146353, COSV66520718; called by muse, mutect2, varscan2
- TEX10 | c.240A>C p.G80= | Silent (SNP) | VAF 77/393 reads (20%) | catalogued as COSV66518167; called by muse, mutect2, varscan2
- TTC7A | c.909C>A p.P303= | Silent (SNP) | VAF 55/196 reads (28%) | catalogued as COSV55414853; called by muse, mutect2, varscan2
